Somatic mutation profile of tumor specimen MP2PRT-PATEKK-TMP1-A (aliquot MP2PRT-PATEKK-TMP1-A-1-0-D-A82L-36) from MP2PRT case MP2PRT-PATEKK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (671 days).
Specimen MP2PRT-PATEKK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0970e122-6a63-415e-aa25-3f06b2dc1e47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATEKK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATEKK-NB1-A-1-0-D-A82L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f019c545-ce56-494d-9b41-5e9aa28987a7

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FMR1 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.595); catalogued as rs372019441, COSV54425115; called by muse, mutect2
- H2AC11 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 74/456 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.392); catalogued as COSV60361674; called by muse, mutect2, varscan2
- H2AC14 | c.320G>A p.G107D | Missense Mutation (SNP) | VAF 15/490 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60799072; called by muse, mutect2
- SATB2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 48/699 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs142825652, COSV99612002; ClinVar: benign; called by muse, mutect2
- WFDC13 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs770984791, COSV57913786; called by muse, mutect2, varscan2
- DOCK8 | c.6115C>T p.Q2039* | Nonsense Mutation (SNP) | VAF 12/343 reads (3%) | called by muse, mutect2
- NLRP2 | c.807G>T p.L269F | Missense Mutation (SNP) | VAF 66/808 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); called by muse, mutect2
